Somatic mutation profile of tumor specimen 0DX0RC from CCDI case PBCNFF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.0 years (2,199 days).
Specimen 0DX0RC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43b97107-688c-45df-b062-ea149af63700.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX0Q0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80e3d846-ed0b-49e0-98b8-c4228b45dac5

The open-access MAF lists 35 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Intron 7, Silent 4, 3'UTR 2, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MUC16 | c.19812G>C p.K6604N | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.041); catalogued as COSV67490366; called by muse, mutect2, varscan2
- NALCN | c.4387A>G p.S1463G | Missense Mutation (SNP) | VAF 277/402 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1219517502; called by muse, mutect2, varscan2
- NELL1 | c.2341T>A p.W781R | Missense Mutation (SNP) | VAF 276/359 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV54253272; called by muse, mutect2, varscan2
- POU3F1 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs1431424857; called by muse, mutect2, varscan2
- PTPRJ | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 196/277 reads (71%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs768693267; called by muse, mutect2, varscan2
- SLC22A3 | c.1405G>A p.G469R | Missense Mutation (SNP) | VAF 170/399 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370257112; called by muse, mutect2, varscan2
- SNRPN | c.547A>T p.T183S | Missense Mutation (SNP) | VAF 218/332 reads (66%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs369210394; called by muse, mutect2, varscan2
- THSD7B | c.3644T>G p.V1215G (on ENST00000272643; = p.V1213G on NM_001316349.2) | Missense Mutation (SNP) | VAF 245/698 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs914946436; called by muse, mutect2, varscan2
- TTC28 | c.5221G>A p.A1741T | Missense Mutation (SNP) | VAF 203/301 reads (67%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs763251506, COSV67417791, COSV67424545; called by muse, mutect2, varscan2
- USP19 | c.1564C>T p.R522W | Missense Mutation (SNP) | VAF 200/300 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243364665, COSV60046942; called by muse, mutect2, varscan2
- CD8B | c.103A>T p.K35* | Nonsense Mutation (SNP) | VAF 95/569 reads (17%) | called by muse, mutect2, varscan2
- COL4A3 | c.880G>T p.G294C | Missense Mutation (SNP) | VAF 235/581 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRMPD2 | c.1952T>G p.F651C | Missense Mutation (SNP) | VAF 27/584 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.339); called by muse, mutect2
- GZMM | c.620C>G p.S207W | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KNTC1 | c.4280T>C p.L1427P | Missense Mutation (SNP) | VAF 231/592 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MXRA5 | c.8305T>G p.L2769V | Missense Mutation (SNP) | VAF 108/145 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NCOR2 | c.34T>A p.W12R | Missense Mutation (SNP) | VAF 142/331 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SLC16A7 | c.16A>T p.S6C | Missense Mutation (SNP) | VAF 139/452 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- TBX5 | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 212/573 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TMTC1 | c.734G>A p.S245N (on ENST00000539277 / NM_001193451.2; = p.S137N on NM_175861.3) | Missense Mutation (SNP) | VAF 156/382 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- UNC80 | c.2081A>C p.K694T | Missense Mutation (SNP) | VAF 31/1031 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.723); called by muse, mutect2
- HLX | c.1239C>G p.G413= | Silent (SNP) | VAF 121/345 reads (35%) | called by muse, mutect2, varscan2
- HOXB1 | c.81C>T p.A27= | Silent (SNP) | VAF 102/171 reads (60%) | catalogued as COSV53318965; called by muse, mutect2, varscan2
- KIF4B | c.2409T>C p.S803= | Silent (SNP) | VAF 302/454 reads (67%) | called by muse, mutect2, varscan2
- KRTAP9-4 | c.138C>T p.S46= | Silent (SNP) | VAF 76/130 reads (58%) | called by muse, mutect2
- ATP6V1E1 | c.209+62T>G | Intron (SNP) | VAF 5/108 reads (5%) | called by muse, mutect2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 27/723 reads (4%) | called by muse, mutect2
- EEF1AKMT2 | c.292-25A>T | Intron (SNP) | VAF 17/146 reads (12%) | called by muse, varscan2
- GYPB | c.270+85A>G | Intron (SNP) | VAF 59/91 reads (65%) | catalogued as rs1443195130; called by muse, mutect2, varscan2
- GYPB | c.270+84C>A | Intron (SNP) | VAF 58/91 reads (64%) | called by muse, mutect2, varscan2
- IFNL1 | c.*87C>G | 3'UTR (SNP) | VAF 30/33 reads (91%) | called by muse, mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.228-53553G>T | Intron (SNP) | VAF 222/504 reads (44%) | called by muse, varscan2
- TTN | c.34523-357A>C | Intron (SNP) | VAF 310/841 reads (37%) | called by muse, mutect2, varscan2
- UCK1 | c.-12G>A | 5'UTR (SNP) | VAF 44/52 reads (85%) | called by muse, mutect2, varscan2
